Somatic mutation profile of tumor specimen TCGA-CM-6165-01A (aliquot TCGA-CM-6165-01A-11D-1650-10) from TCGA case TCGA-CM-6165, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 74.7 years (27,302 days).
Specimen TCGA-CM-6165-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2303ccfb-fb78-4fcd-8de4-45d68904e76b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-6165-10A (Blood Derived Normal), aliquot TCGA-CM-6165-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7625eb29-dc73-4d38-8c51-7e027e066b99

The open-access MAF lists 116 somatic variants for this specimen: 85 protein-altering or splice-affecting, 29 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 29, Nonsense Mutation 6, Splice Site 3, Frame Shift Del 3, Frame Shift Ins 2, 3'UTR 1, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 88/287 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM100517, COSV61684465, COSV61684539, COSV61685012; called by muse, mutect2, varscan2
- TP53 | c.993+1G>T p.X331_splice | Splice Site (SNP) | VAF 41/128 reads (32%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: not provided / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.3251G>A p.S1084N | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs1482448695, COSV70048325; called by muse, mutect2, varscan2
- ABCF3 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99491064; called by muse, mutect2, varscan2
- ACAP3 | c.2276G>A p.G759D | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1418211401, COSV100330320; called by muse, mutect2, varscan2
- ACOT11 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs144192149; called by muse, mutect2, varscan2
- ADAMTS16 | c.3443C>T p.T1148M | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs775064149, COSV57009673; called by muse, mutect2, varscan2
- ANK2 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.436); catalogued as rs901601971, COSV52148836, COSV52150935; called by muse, mutect2, varscan2
- ANK2 | c.8051A>T p.E2684V | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52193498; called by muse, mutect2, varscan2
- ARC | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs774341447, COSV63079948; called by muse, mutect2, varscan2
- ATG9B | c.2263G>A p.V755M | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV52496822; called by muse, mutect2, varscan2
- ATP2B4 | c.2147G>T p.G716V | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV58185129; called by muse, mutect2, varscan2
- BCAS2 | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 145/423 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV65767948; called by muse, mutect2, varscan2
- BNIPL | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 71/242 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs764413830, COSV54845752; called by muse, mutect2, varscan2
- CANX | c.1295A>G p.D432G | Missense Mutation (SNP) | VAF 243/709 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); catalogued as COSV56007396; called by mutect2, varscan2
- CC2D1A | c.1802G>T p.G601V | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV58786703; called by muse, mutect2, varscan2
- CD1E | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs111388079, COSV63770590; called by muse, mutect2, varscan2
- CEACAM5 | c.586G>C p.G196R | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV55755881; called by muse, mutect2, varscan2
- CETP | c.1413C>A p.F471L | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV52364709; called by muse, mutect2, varscan2
- CNTN6 | c.1162G>T p.A388S | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs768433383, COSV63192862; called by muse, mutect2, varscan2
- COL8A1 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 43/146 reads (29%) | catalogued as COSV53744013; called by muse, mutect2, varscan2
- CYBB | c.1118A>G p.K373R | Missense Mutation (SNP) | VAF 101/144 reads (70%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as COSV66086559; called by muse, mutect2, varscan2
- DLG2 | c.440C>A p.P147H (on ENST00000650630 / NM_001351274.2; = p.P110H on NM_001142699.3) | Missense Mutation (SNP) | VAF 128/290 reads (44%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.91); catalogued as COSV65882583; called by muse, mutect2, varscan2
- FIZ1 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs1200517702, COSV99684784; called by muse, mutect2, varscan2
- FKBP8 | c.1199G>T p.G400V (on ENST00000222308 / NM_001308373.2; = p.G401V on NM_012181.5) | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.851); catalogued as COSV55894466; called by muse, mutect2, varscan2
- GAD2 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52152616; called by muse, mutect2, varscan2
- GDPD4 | c.1349T>C p.I450T | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as rs373177608, COSV60023797; called by muse, mutect2, varscan2
- GRIN2A | c.3863G>A p.R1288H | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778951185, COSV58035660; called by muse, mutect2, varscan2
- GRM1 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51115368; called by muse, mutect2, varscan2
- HNRNPK | c.155A>T p.K52M | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57938227; called by muse, mutect2, varscan2
- HRC | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763236818, COSV99418491; called by muse, mutect2
- IGSF9B | c.3407G>A p.R1136Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs758894455, COSV58073930; called by muse, mutect2, varscan2
- IVL | c.1518G>T p.Q506H | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV100908088; called by muse, mutect2, varscan2
- KIAA2026 | c.2437C>T p.R813C | Missense Mutation (SNP) | VAF 135/403 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763763990, COSV67353524, COSV67358307; called by muse, mutect2, varscan2
- KIRREL3 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.9); catalogued as COSV73109859; called by muse, mutect2, varscan2
- LONRF3 | c.1345G>A p.D449N (on ENST00000371628 / NM_001031855.3; = p.D408N on NM_024778.5) | Missense Mutation (SNP) | VAF 94/132 reads (71%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV59157689; called by muse, mutect2, varscan2
- LRRC7 | c.2288+1G>T p.X763_splice (on ENST00000651989 / NM_001370785.2; = p.X730_splice on NM_001330635.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 32/126 reads (25%) | catalogued as COSV50652302; called by muse, mutect2, varscan2
- MCM4 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV50623288; called by muse, mutect2, varscan2
- MGARP | c.589A>T p.T197S | Missense Mutation (SNP) | VAF 151/413 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV101299249, COSV67449072; called by muse, mutect2, varscan2
- MRPS5 | c.372G>T p.K124N | Missense Mutation (SNP) | VAF 233/608 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV55535706; called by muse, mutect2, varscan2
- MUC16 | c.21329C>A p.P7110H | Missense Mutation (SNP) | VAF 119/336 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); catalogued as COSV67500537; called by muse, mutect2, varscan2
- NEK10 | c.2227G>C p.E743Q | Missense Mutation (SNP) | VAF 74/221 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV55366579; called by muse, mutect2, varscan2
- OR14K1 | c.403A>G p.S135G | Missense Mutation (SNP) | VAF 96/275 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99315556; called by muse, mutect2, varscan2
- P2RX7 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.077); catalogued as COSV55858194; called by muse, mutect2, varscan2
- PADI3 | c.296G>A p.S99N | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as COSV64935588; called by muse, mutect2, varscan2
- PARP9 | c.1891C>G p.Q631E | Missense Mutation (SNP) | VAF 142/477 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64452236; called by muse, mutect2, varscan2
- PCDHB15 | c.1937A>G p.D646G | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV99179313; called by muse, mutect2, varscan2
- PCDHGA12 | c.2138C>G p.A713G | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.087); catalogued as COSV52742753, COSV99342914; called by muse, mutect2, varscan2
- PCF11 | c.3122G>T p.G1041V | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV53538647; called by muse, mutect2, varscan2
- PITPNM1 | c.3604C>T p.R1202C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs778114702, COSV54159792, COSV54161542; called by muse, mutect2, varscan2
- PLA2G4A | c.276G>T p.M92I | Missense Mutation (SNP) | VAF 121/353 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV66557670; called by muse, mutect2, varscan2
- PLCB1 | c.2068G>A p.D690N | Missense Mutation (SNP) | VAF 82/268 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV62071742; called by muse, mutect2, varscan2
- POLDIP3 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 89/273 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1385914300, COSV99349431; called by muse, varscan2
- POLR3B | c.2698C>T p.R900C | Missense Mutation (SNP) | VAF 17/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755326914, COSV57284811, COSV99943970; called by muse, mutect2
- PRKAG1 | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 82/285 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV60295090; called by muse, mutect2, varscan2
- PROX1 | c.1976G>T p.C659F | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); catalogued as COSV54784742; called by muse, mutect2, varscan2
- PTPRK | c.2543G>A p.R848H (on ENST00000368215 / NM_001291984.2; = p.R849H on NM_002844.4) | Missense Mutation (SNP) | VAF 76/207 reads (37%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); catalogued as rs149112314; called by muse, mutect2, varscan2
- RAB3D | c.408G>T p.K136N | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55793263; called by muse, mutect2, varscan2
- RNF180 | c.679A>G p.K227E | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV99685052; called by muse, mutect2, varscan2
- ROS1 | c.1048G>T p.A350S | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV63862596; called by muse, mutect2, varscan2
- RPL22 | c.44dup p.K16Efs*9 | Frame Shift Ins (INS) | VAF 13/38 reads (34%) | catalogued as rs759765382; called by mutect2, varscan2
- SARDH | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs755017202, COSV53836478; called by muse, mutect2, varscan2
- SEMA6A | c.1942G>A p.V648I | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.028); catalogued as rs778751794, COSV56714113; called by muse, mutect2, varscan2
- STC1 | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 80/213 reads (38%) | SIFT tolerated (0.89); PolyPhen benign (0.011); catalogued as rs139152218, COSV51687784, COSV51688923; called by muse, mutect2, varscan2
- STK17A | c.866T>C p.V289A | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV100082340; called by muse, mutect2
- SYT16 | c.1457C>A p.P486Q | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as COSV70860425; called by muse, mutect2, varscan2
- TAF12 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 90/245 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as rs777359513, COSV56041047; called by muse, mutect2, varscan2
- TAF13 | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 63/182 reads (35%) | catalogued as COSV58040690; called by muse, mutect2, varscan2
- TBL2 | c.1175G>T p.G392V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.539); catalogued as COSV99979788; called by muse, mutect2, varscan2
- TCF7L2 | c.840C>A p.Y280* (on ENST00000355995 / NM_001367943.1; = p.Y257* on NM_030756.5) | Nonsense Mutation (SNP) | VAF 82/200 reads (41%) | catalogued as COSV53338915; called by muse, mutect2, varscan2
- THBS2 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); catalogued as rs375611577, COSV100828129; called by muse, mutect2, varscan2
- TMEM132B | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.8); PolyPhen benign (0.09); catalogued as rs919773875, COSV54762508; called by muse, mutect2, varscan2
- TMEM132D | c.2314G>T p.V772F | Missense Mutation (SNP) | VAF 108/334 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.246); catalogued as COSV67163056; called by muse, mutect2, varscan2
- TOP2B | c.3469G>T p.E1157* (on ENST00000264331 / NM_001330700.2; = p.E1152* on NM_001068.3) | Nonsense Mutation (SNP) | VAF 33/78 reads (42%) | catalogued as COSV51978174; called by muse, mutect2, varscan2
- TRPM2 | c.171A>T p.E57D | Missense Mutation (SNP) | VAF 14/271 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV100309481; called by muse, mutect2
- TTN | c.22097C>T p.A7366V (on ENST00000591111; = p.A6439V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/145 reads (32%) | PolyPhen benign (0.054); catalogued as COSV60402866; called by muse, mutect2, varscan2
- USP9X | c.1898-1G>A p.X633_splice | Splice Site (SNP) | VAF 117/163 reads (72%) | catalogued as COSV61076412; called by muse, mutect2, varscan2
- VASN | c.1620del p.R542Gfs*86 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | catalogued as rs1167049686; called by mutect2, pindel, varscan2
- ZDHHC13 | c.1513G>A p.G505R | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67982375; called by muse, mutect2, varscan2
- ZNF99 | c.1359C>A p.Y453* | Nonsense Mutation (SNP) | VAF 49/137 reads (36%) | catalogued as COSV68057280; called by muse, mutect2, varscan2
- APC | c.4203del p.I1401Mfs*14 | Frame Shift Del (DEL) | VAF 132/232 reads (57%) | called by mutect2, pindel, varscan2
- ATP8B1 | c.2425dup p.I809Nfs*11 | Frame Shift Ins (INS) | VAF 122/253 reads (48%) | called by mutect2, pindel, varscan2
- CDRT1 | c.386_389del p.T129Sfs*26 | Frame Shift Del (DEL) | VAF 120/393 reads (31%) | called by mutect2, varscan2
- IWS1 | c.1527_1529dup p.E509dup | In Frame Ins (INS) | VAF 254/782 reads (32%) | called by mutect2, pindel, varscan2
- TRAF3IP2 | c.1673dup p.Y558* | Nonsense Mutation (INS) | VAF 12/51 reads (24%) | called by mutect2, pindel, varscan2
- ABCA4 | c.3618T>C p.N1206= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV64679329; called by muse, mutect2, varscan2
- ACTB | c.162G>T p.V54= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV59322023; called by muse, mutect2, varscan2
- APOBEC3D | c.852C>A p.V284= | Silent (SNP) | VAF 52/174 reads (30%) | catalogued as COSV53329073; called by muse, mutect2, varscan2
- ARHGAP22 | c.1335C>T p.G445= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs377495248, COSV51003252; called by muse, mutect2, varscan2
- ARHGEF4 | c.1242C>A p.I414= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV58131821; called by muse, mutect2, varscan2
- ARHGEF6 | c.747C>T p.I249= | Silent (SNP) | VAF 55/73 reads (75%) | catalogued as COSV51696861; called by muse, mutect2, varscan2
- BTBD11 | c.2349C>T p.C783= (on ENST00000280758 / NM_001018072.2; = p.C320= on NM_001017523.2) | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs749124936, COSV55016618; called by muse, mutect2, varscan2
- CACNG7 | c.546C>T p.A182= | Silent (SNP) | VAF 84/223 reads (38%) | catalogued as rs374671812, COSV55817552; called by muse, mutect2, varscan2
- CDH23 | c.2637C>T p.N879= | Silent (SNP) | VAF 49/141 reads (35%) | catalogued as COSV99034545, COSV99824478; called by muse, mutect2, varscan2
- CRNN | c.486G>A p.A162= | Silent (SNP) | VAF 78/220 reads (35%) | catalogued as rs201282523, COSV55123222, COSV99664107; called by muse, mutect2, varscan2
- CROCC | c.2073C>T p.R691= | Silent (SNP) | VAF 35/198 reads (18%) | catalogued as rs757341913, COSV65015343; called by muse, mutect2, varscan2
- DCAF8L1 | c.234C>T p.D78= | Silent (SNP) | VAF 10/254 reads (4%) | catalogued as COSV101491582; called by muse, mutect2
- DLGAP2 | c.345C>T p.D115= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as rs780412370, COSV70104356; called by mutect2, varscan2
- DNAH2 | c.12942C>T p.S4314= | Silent (SNP) | VAF 58/198 reads (29%) | catalogued as COSV66728679; called by muse, mutect2, varscan2
- EPPK1 | c.2814G>T p.L938= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs1554660781, COSV73262481; called by muse, mutect2, varscan2
- FAT3 | c.11811C>T p.Y3937= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs1243216525, COSV53138041; called by muse, varscan2
- FCGR1A | c.1122G>A p.T374= | Silent (SNP) | VAF 172/468 reads (37%) | catalogued as rs587640055, COSV64986189; called by muse, mutect2, varscan2
- GTF3C2 | c.219G>A p.Q73= | Silent (SNP) | VAF 54/124 reads (44%) | catalogued as COSV53129167; called by muse, mutect2, varscan2
- IGFBP5 | c.705C>T p.G235= | Silent (SNP) | VAF 58/169 reads (34%) | catalogued as COSV99289116; called by muse, mutect2, varscan2
- KIAA1614 | c.3531G>A p.R1177= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV62552010; called by muse, mutect2, varscan2
- LBR | c.1095C>G p.V365= | Silent (SNP) | VAF 81/205 reads (40%) | catalogued as rs1193948853, COSV55292304; called by muse, mutect2, varscan2
- OR10V1 | c.756G>A p.Q252= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as COSV100276345; called by muse, mutect2
- RCVRN | c.159C>T p.Y53= | Silent (SNP) | VAF 56/154 reads (36%) | catalogued as rs1052015240, COSV56841443; called by muse, mutect2, varscan2
- RSPH1 | c.837G>A p.R279= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as rs766003560, COSV52321509; called by muse, mutect2, varscan2
- SLC35D1 | c.813C>T p.Y271= | Silent (SNP) | VAF 45/146 reads (31%) | catalogued as rs372859338; ClinVar: likely benign; called by muse, mutect2, varscan2
- SYNE1 | c.5454C>T p.G1818= (on ENST00000367255 / NM_182961.4; = p.G1825= on NM_033071.3) | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV54931077; called by muse, mutect2, varscan2
- TREML4 | c.102G>A p.Q34= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as COSV58386704; called by muse, mutect2, varscan2
- USP29 | c.2529C>T p.S843= | Silent (SNP) | VAF 47/135 reads (35%) | catalogued as rs776535799, COSV54141536; called by muse, mutect2, varscan2
- XIRP2 | c.1641C>A p.L547= (on ENST00000628543; = p.L722= on NM_152381.6) | Silent (SNP) | VAF 69/190 reads (36%) | catalogued as COSV54739906; called by muse, mutect2, varscan2
- ATAD3C | c.*162A>G | 3'UTR (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- MIR382 | n.45C>T | RNA (SNP) | VAF 21/167 reads (13%) | catalogued as rs377201140; called by muse, mutect2, varscan2
